Gene-level copy-number profile of tumor specimen TCGA-DK-A2HX-01A from TCGA case TCGA-DK-A2HX, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 80.3 years (29,332 days).
Specimen TCGA-DK-A2HX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.2e692b86-8009-4a73-b0bc-b0c19a18042e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-A2HX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c7979bb-9084-4865-b054-fbf79c04ec90

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 419; copy number 2: 5,023; copy number 3: 18,094; copy number 4: 21,298; copy number 5: 3,809; copy number 6: 6,713; copy number 7: 1,109; copy number 8: 1,349; copy number 9: 134; copy number 10: 821; copy number 11: 32; copy number 12: 644; copy number 13: 30; copy number 14: 92; copy number 16: 8; copy number 17: 99; copy number 18: 145.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-A2HX-01A-12D-A18E-01): tumor purity 0.49, ploidy 3.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,005 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–155,885,199, 573 genes, copy number 11–12 (within-gene range 3–12) (broad region; genes not listed).
- chr4:76,435,229–77,150,437, 16 genes, copy number 9 (within-gene range 4–9): SHROOM3, AC112249.1, RNU6-145P, MIR4450, MIR548AH, SHROOM3-AS1, AC107072.1, AC104687.2, AC104687.1, SOWAHB, SEPTIN11, TXNP6, CCNI, RPL7P17, AC104771.1, RNU6-1187P.
- chr4:77,216,416–77,216,878, 1 gene, copy number 9: AC008638.3.
- chr4:148,445,703–149,896,233, 15 genes, copy number 10 (within-gene range 6–10): AC002460.2, ASS1P8, RNA5SP166, AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355, IQCM, AC108168.1, AC093893.1, AKIRIN2P1.
- chr4:152,320,544–163,473,754, 155 genes, copy number 9–13 (within-gene range 6–13) (broad region; genes not listed).
- chr10:44,712–254,637, 6 genes, copy number 16: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297.
- chr10:282,015–430,504, 2 genes, copy number 16: RNA5SP298, RN7SL754P.
- chr10:1,957,589–19,790,401, 298 genes, copy number 10–18 (within-gene range 8–18) (broad region; genes not listed).
- chr10:37,976,825–38,783,108, 28 genes, copy number 9: ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr13:68,861,284–84,902,424, 160 genes, copy number 9–14 (broad region; genes not listed).
- chr19:29,698,886–46,392,981, 751 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 419. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
